Somatic mutation profile of tumor specimen 0DVVL0 from CCDI case PBCMLB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Renal pelvis; Age at diagnosis: 11.8 years (4,292 days).
Specimen 0DVVL0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3d78d8a-3b86-418f-9b07-7561bd2bd890.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVVMB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8699bb1-ee79-4162-a235-f41288441911

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 3, Frame Shift Del 2, 3'UTR 2, 5'UTR 1, Nonsense Mutation 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 195/868 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1263485639, COSV51418888; called by muse, mutect2, varscan2
- BSN | c.6230del p.G2077Efs*117 | Frame Shift Del (DEL) | VAF 86/196 reads (44%) | catalogued as COSV56514781; called by mutect2, varscan2
- FCER2 | c.192C>A p.V64= | Splice Region (SNP) | VAF 84/219 reads (38%) | catalogued as COSV60916083; called by muse, mutect2, varscan2
- IL17RE | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 38/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1402887286; called by muse, mutect2
- KRT40 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 126/284 reads (44%) | catalogued as rs1218214820, COSV66696639; called by muse, mutect2, varscan2
- MYO10 | c.5425G>A p.E1809K | Missense Mutation (SNP) | VAF 241/718 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57029371; called by muse, mutect2, varscan2
- TAF7L | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 299/956 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV61258118; called by muse, mutect2, varscan2
- AADACL2 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 214/686 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, varscan2
- POGK | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 203/1234 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- RRP15 | c.481_482del p.N161Sfs*14 | Frame Shift Del (DEL) | VAF 125/1090 reads (11%) | called by mutect2, varscan2
- STAG2 | c.801_803del p.L268del | In Frame Del (DEL) | VAF 212/556 reads (38%) | called by mutect2, varscan2
- ABCA12 | c.6273C>T p.L2091= (on ENST00000272895 / NM_173076.3; = p.L1773= on NM_015657.3) | Silent (SNP) | VAF 178/496 reads (36%) | catalogued as rs1434972754; called by muse, mutect2, varscan2
- LRRIQ1 | c.3024C>T p.G1008= | Silent (SNP) | VAF 256/777 reads (33%) | catalogued as rs758936698, COSV67829876; called by muse, mutect2, varscan2
- OR10C1 | c.549G>A p.Q183= (on ENST00000622521; = p.Q181= on NM_013941.3) | Silent (SNP) | VAF 67/188 reads (36%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/106 reads (9%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 10/101 reads (10%) | called by muse, varscan2
- FAM181A | c.*4C>T | 3'UTR (SNP) | VAF 52/139 reads (37%) | catalogued as rs150198804; called by muse, mutect2, varscan2
- FOXO4 | c.*37G>A | 3'UTR (SNP) | VAF 16/496 reads (3%) | called by muse, mutect2
- SETD9 | c.-31G>A | 5'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- SLIT3 | c.486-33T>G | Intron (SNP) | VAF 47/162 reads (29%) | called by muse, mutect2, varscan2
